Somatic mutation profile of tumor specimen TCGA-D7-6822-01A (aliquot TCGA-D7-6822-01A-11D-1882-08) from TCGA case TCGA-D7-6822, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 77.2 years (28,214 days).
Specimen TCGA-D7-6822-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9cff16c-73c7-4e5c-b8c0-c17c6c05879e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D7-6822-10A (Blood Derived Normal), aliquot TCGA-D7-6822-10A-01D-1882-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5801faa2-8c08-4927-a678-735ff4498fbf

The open-access MAF lists 260 somatic variants for this specimen: 203 protein-altering or splice-affecting, 45 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 187, Silent 45, Intron 6, Nonsense Mutation 6, Frame Shift Del 6, RNA 4, Frame Shift Ins 2, Splice Site 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 15/87 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TENT5D | c.205A>C p.S69R | Missense Mutation (SNP) | VAF 36/91 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57634984, COSV57635195, COSV57638952; called by muse, mutect2, varscan2
- ABCA12 | c.5239C>T p.L1747F (on ENST00000272895 / NM_173076.3; = p.L1429F on NM_015657.3) | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV55974418; called by muse, mutect2, varscan2
- ABCB11 | c.3784G>T p.D1262Y | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55600358; called by muse, mutect2, varscan2
- ACKR4 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 37/242 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as COSV51443483; called by muse, mutect2, varscan2
- ACSL3 | c.126T>G p.Y42* | Nonsense Mutation (SNP) | VAF 36/145 reads (25%) | catalogued as COSV62484662; called by muse, mutect2, varscan2
- ADAMTS20 | c.4865A>G p.K1622R | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.017); catalogued as COSV101240586, COSV67138663; called by muse, mutect2, varscan2
- ADAMTS5 | c.1107T>G p.D369E | Missense Mutation (SNP) | VAF 39/59 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53183156, COSV53184863; called by muse, mutect2, varscan2
- ADGRB3 | c.1462A>C p.T488P | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV65418351; called by muse, mutect2, varscan2
- ADGRE3 | c.1921-2A>G p.X641_splice | Splice Site (SNP) | VAF 14/178 reads (8%) | catalogued as COSV53732787; called by muse, mutect2
- ADGRL4 | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.16); catalogued as COSV66065627; called by muse, mutect2, varscan2
- AL592490.1 | c.1041A>C p.K347N | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV69427756; called by muse, mutect2, varscan2
- ALDH5A1 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV62373297; called by muse, mutect2, varscan2
- AMPH | c.665T>A p.V222E | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.173); catalogued as COSV57755953; called by muse, mutect2, varscan2
- ANO5 | c.2201T>G p.L734R | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV61090034; called by muse, mutect2, varscan2
- ARHGAP35 | c.2461T>G p.L821V | Missense Mutation (SNP) | VAF 80/206 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0.027); catalogued as rs1448478725, COSV68335486; called by muse, mutect2, varscan2
- ARSF | c.628G>A p.G210S | Missense Mutation (SNP) | VAF 37/47 reads (79%) | SIFT tolerated (0.08); PolyPhen benign (0.359); catalogued as rs753420813, COSV63839605; called by muse, mutect2, varscan2
- ART5 | c.228G>C p.E76D | Missense Mutation (SNP) | VAF 49/96 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV51707021; called by muse, mutect2, varscan2
- ASXL1 | c.1452G>C p.E484D | Missense Mutation (SNP) | VAF 52/320 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.615); catalogued as COSV60121452; called by muse, mutect2, varscan2
- ATRN | c.3479T>G p.L1160R | Missense Mutation (SNP) | VAF 71/247 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV53533895; called by muse, mutect2, varscan2
- ATRNL1 | c.1786T>A p.F596I | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV61816126; called by muse, mutect2, varscan2
- BMP5 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100895773, COSV63706311; called by muse, mutect2, varscan2
- BNC1 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV61759068; called by muse, mutect2, varscan2
- CAMK4 | c.278T>G p.L93R | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56681866; called by muse, varscan2
- CAPN12 | c.347T>C p.L116P | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1370199524; called by muse, mutect2
- CBFB | c.20A>C p.D7A | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV52001151; called by muse, mutect2, varscan2
- CBLN1 | c.417T>G p.I139M | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54655039; called by muse, mutect2, varscan2
- CCT4 | c.444G>T p.L148F | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs528619072, COSV66702010; called by muse, mutect2, varscan2
- CD1E | c.209T>A p.V70D | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV63772780; called by muse, mutect2, varscan2
- CDH11 | c.1070A>C p.K357T | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV51753026, COSV51757269, COSV99220171; called by muse, mutect2, varscan2
- CDH2 | c.2689C>G p.L897V | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52295132; called by muse, mutect2, varscan2
- CDH2 | c.176A>C p.K59T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52295143; called by muse, mutect2, varscan2
- CDH6 | c.1334T>G p.L445R | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.139); catalogued as COSV54077754; called by muse, mutect2, varscan2
- CDK12 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV71002806; called by muse, mutect2, varscan2
- CFAP54 | c.6516A>C p.K2172N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.51); PolyPhen benign (0.062); catalogued as COSV61575050; called by muse, mutect2, varscan2
- CFHR1 | c.421A>T p.R141W | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV57629078; called by muse, mutect2, varscan2
- CFHR1 | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as COSV57629091; called by muse, mutect2, varscan2
- CFHR2 | c.444A>C p.K148N | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV66380994; called by muse, mutect2, varscan2
- CLSTN2 | c.2156A>C p.E719A | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV71718855, COSV71724806; called by muse, mutect2, varscan2
- CNOT1 | c.5042T>C p.L1681P | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV55322073; called by muse, mutect2, varscan2
- CNTNAP5 | c.2495T>G p.L832R | Missense Mutation (SNP) | VAF 54/156 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV70474139, COSV99081553; called by muse, mutect2, varscan2
- COL12A1 | c.8003A>G p.E2668G | Missense Mutation (SNP) | VAF 27/134 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV59407207; called by muse, mutect2, varscan2
- COL15A1 | c.3265T>A p.F1089I | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV66645994, COSV66648975; called by muse, mutect2, varscan2
- COL22A1 | c.2548T>G p.L850V | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT tolerated (1); PolyPhen possibly damaging (0.857); catalogued as COSV57358961, COSV57359434; called by muse, mutect2, varscan2
- CSMD1 | c.8044G>A p.G2682S (on ENST00000520002; = p.G2681S on NM_033225.6) | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs757892398, COSV59338295; called by muse, mutect2, varscan2
- CSMD3 | c.10797A>C p.K3599N (on ENST00000297405 / NM_001363185.1; = p.K3430N on NM_052900.3) | Missense Mutation (SNP) | VAF 72/392 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV52133513, COSV99836776; called by muse, mutect2, varscan2
- CSMD3 | c.4369T>C p.F1457L (on ENST00000297405 / NM_001363185.1; = p.F1353L on NM_052900.3) | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV52308721; called by muse, mutect2, varscan2
- CSMD3 | c.3179T>G p.L1060R (on ENST00000297405 / NM_001363185.1; = p.L956R on NM_052900.3) | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52308736; called by muse, mutect2, varscan2
- CTNNB1 | c.1016C>A p.T339N | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV62718628; called by muse, mutect2, varscan2
- DLG2 | c.2391A>C p.K797N | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54682703; called by muse, mutect2, varscan2
- DLGAP3 | c.767A>G p.K256R | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.039); catalogued as COSV52397417; called by muse, mutect2, varscan2
- DNAI1 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs150107677; called by muse, mutect2, varscan2
- DOCK10 | c.217T>G p.L73V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV51426928; called by muse, mutect2, varscan2
- E2F7 | c.1706C>T p.S569L | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1172218996, COSV59743375; called by muse, mutect2, varscan2
- ELMOD1 | c.430T>G p.F144V | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV56196199; called by muse, mutect2, varscan2
- ESYT1 | c.2348T>A p.V783E | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.715); catalogued as COSV57276198; called by muse, mutect2, varscan2
- FGD2 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs183698723; called by muse, mutect2, varscan2
- FGF10 | c.394T>G p.L132V | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.536); catalogued as COSV52939407; called by muse, mutect2, varscan2
- FLG | c.3907A>G p.R1303G | Missense Mutation (SNP) | VAF 107/721 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.014); catalogued as COSV64246755; called by muse, mutect2, varscan2
- FLG2 | c.886A>C p.S296R | Missense Mutation (SNP) | VAF 54/578 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV66167157; called by muse, mutect2
- FRMD4A | c.2843C>T p.T948I | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT tolerated (0.3); PolyPhen benign (0.076); catalogued as COSV62269029; called by muse, mutect2, varscan2
- FRMPD4 | c.3220C>A p.Q1074K | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.047); catalogued as COSV66222780; called by muse, mutect2, varscan2
- GABRA1 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs779065852, COSV50118113; called by muse, mutect2, varscan2
- GABRA1 | c.1202A>G p.K401R | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0.124); catalogued as rs745362654, COSV50118164; called by muse, mutect2, varscan2
- GOLGA4 | c.2063C>T p.S688L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV62711972, COSV62713685; called by muse, mutect2, varscan2
- GPR83 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.679); catalogued as COSV54720595; called by muse, mutect2, varscan2
- GPRC5D | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as rs1050579210, COSV57433443; called by muse, mutect2, varscan2
- GRID1 | c.2774T>G p.L925R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.854); catalogued as COSV60051217; called by muse, mutect2, varscan2
- GRIK1 | c.2409A>C p.E803D | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV58731219; called by muse, mutect2, varscan2
- GUCY2D | c.2890C>T p.R964C | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as rs765051553, COSV54696059; called by muse, mutect2, varscan2
- HDX | c.1499A>C p.E500A | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52982601; called by muse, mutect2, varscan2
- HGF | c.1811G>A p.C604Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV55956272; called by muse, mutect2, varscan2
- HMCN1 | c.7125A>C p.K2375N | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.572); catalogued as COSV54938876; called by muse, mutect2, varscan2
- HMCN1 | c.9886C>T p.R3296* | Nonsense Mutation (SNP) | VAF 32/134 reads (24%) | catalogued as COSV54938886; called by muse, mutect2, varscan2
- HS3ST4 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 105/198 reads (53%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs780566032, COSV58826575; called by muse, mutect2, varscan2
- IL1RAPL1 | c.866T>G p.F289C | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as COSV56298396; called by muse, mutect2, varscan2
- INPP5A | c.961A>G p.I321V | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as rs748008299, COSV61252992; called by muse, mutect2, varscan2
- INTU | c.1588T>A p.L530M | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1190413815, COSV58874479; called by muse, mutect2, varscan2
- ITPRID1 | c.1109A>C p.N370T | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV60082191; called by muse, mutect2
- KCNT2 | c.1425A>C p.E475D | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV54107250; called by muse, mutect2, varscan2
- KIF14 | c.2230T>C p.C744R | Missense Mutation (SNP) | VAF 121/273 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV66264010; called by muse, mutect2, varscan2
- KPNA5 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV62654475, COSV62654527; called by muse, mutect2, varscan2
- LMX1B | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 48/74 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1161738395, CM1210013, COSV62741108; called by muse, mutect2, varscan2
- LRP1 | c.8021A>G p.D2674G | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV54525015; called by muse, mutect2, varscan2
- LRRC3B | c.202T>G p.L68V | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.137); catalogued as COSV67521537; called by muse, mutect2, varscan2
- LRRC4B | c.1019G>C p.C340S | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65350756; called by muse, mutect2, varscan2
- LRRC7 | c.2093G>A p.G698E (on ENST00000651989 / NM_001370785.2; = p.G665E on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs376367677; called by muse, mutect2, varscan2
- LTV1 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.061); catalogued as rs747127841, COSV62536324, COSV62536759; called by muse, mutect2, varscan2
- MACROH2A2 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57160824; called by muse, mutect2, varscan2
- MAGI2 | c.2845A>C p.T949P | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV62650273; called by muse, mutect2, varscan2
- MAP2 | c.4371A>C p.E1457D | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV52286196; called by muse, mutect2, varscan2
- MCHR2 | c.741G>A p.M247I | Missense Mutation (SNP) | VAF 36/161 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.1); catalogued as COSV56008339; called by muse, mutect2, varscan2
- MOGS | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs749160883, COSV51971550; called by muse, mutect2, varscan2
- MPPED2 | c.458A>G p.Q153R | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.77); catalogued as COSV63901096; called by muse, mutect2, varscan2
- MUC4 | c.2630C>G p.S877C | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.709); catalogued as COSV62125595, COSV62190452; called by mutect2, varscan2
- MYOZ1 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63772572; called by muse, mutect2, varscan2
- NAALAD2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs138601382, COSV58967049; called by muse, mutect2, varscan2
- NBEA | c.3932C>G p.P1311R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.326); catalogued as COSV59820803; called by muse, mutect2, varscan2
- NDST4 | c.1118A>C p.E373A | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as COSV52131064, COSV52136540; called by muse, mutect2, varscan2
- NLRP10 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as rs775252675, COSV60782505; called by muse, mutect2, varscan2
- NMNAT2 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV54271724; called by muse, mutect2, varscan2
- NMRK2 | c.278A>G p.D93G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV51456493; called by muse, mutect2, varscan2
- NRXN3 | c.1141T>G p.F381V (on ENST00000335750 / NM_001330195.2; = p.F8V on NM_004796.6) | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV59804148; called by muse, mutect2, varscan2
- NSD3 | c.3814G>C p.E1272Q | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs780032475, COSV57673944; called by muse, mutect2, varscan2
- OGFRL1 | c.732A>C p.K244N | Missense Mutation (SNP) | VAF 183/820 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV64972498; called by muse, mutect2, varscan2
- OR2J3 | c.824A>C p.K275T | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV65849041, COSV65849641; called by muse, mutect2, varscan2
- OR51L1 | c.923A>G p.K308R | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs999370285, COSV58625691; called by muse, mutect2, varscan2
- OR8H1 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 33/111 reads (30%) | catalogued as COSV57295814; called by muse, mutect2, varscan2
- OR8K1 | c.338T>C p.F113S | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV54404470; called by muse, mutect2, varscan2
- PAX1 | c.814G>T p.G272W | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68273063, COSV68273325; called by muse, mutect2, varscan2
- PCDH1 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 48/71 reads (68%) | SIFT tolerated (0.65); PolyPhen benign (0.428); catalogued as rs374705686; called by muse, mutect2, varscan2
- PCDH11X | c.140T>G p.L47R | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV53501548; called by muse, mutect2, varscan2
- PCDHB1 | c.1419A>T p.K473N | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV60632003, COSV60633167; called by muse, mutect2, varscan2
- PCLO | c.7735A>C p.T2579P | Missense Mutation (SNP) | VAF 77/213 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61663674; called by muse, mutect2, varscan2
- PDZD9 | c.713C>T p.S238F (on ENST00000424898 / NM_001363519.1; = p.S178F on NM_173806.4) | Missense Mutation (SNP) | VAF 138/244 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51674017; called by muse, mutect2, varscan2
- PGS1 | c.491A>C p.D164A | Missense Mutation (SNP) | VAF 72/301 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53148455; called by muse, mutect2, varscan2
- PID1 | c.626A>G p.K209R (on ENST00000354069 / NM_001330156.1; = p.K207R on NM_017933.5) | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.995); catalogued as COSV100819598, COSV62482403; called by muse, mutect2, varscan2
- PLCB1 | c.3011A>C p.K1004T | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.597); catalogued as COSV62043198; called by muse, mutect2, varscan2
- PLCL1 | c.3004T>G p.F1002V | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as COSV101406884; called by muse, varscan2
- PM20D1 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs750662275, COSV65649621; called by muse, mutect2, varscan2
- POLR3A | c.1592C>A p.T531N | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64932050; called by muse, mutect2, varscan2
- PPP1R3A | c.2779A>G p.T927A | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs373483153; called by muse, mutect2, varscan2
- PRAMEF7 | c.1063T>G p.L355V | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100435040; called by muse, mutect2, varscan2
- PRKG1 | c.755T>C p.L252P | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64809489; called by muse, mutect2, varscan2
- PSG1 | c.989-1G>C p.X330_splice | Splice Site (SNP) | VAF 39/284 reads (14%) | catalogued as rs769909104, COSV99741324; called by muse, mutect2, varscan2
- PTPRD | c.4729A>T p.K1577* | Nonsense Mutation (SNP) | VAF 32/170 reads (19%) | catalogued as COSV61957320, COSV61979263; called by muse, mutect2, varscan2
- PXDNL | c.2779C>T p.P927S | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV62497829; called by muse, mutect2, varscan2
- QRFPR | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100543808, COSV57677366; called by muse, mutect2, varscan2
- RAD54L2 | c.2154A>C p.E718D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.339); catalogued as COSV56581454; called by muse, mutect2, varscan2
- RANGAP1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.186); catalogued as COSV62364673; called by muse, mutect2, varscan2
- RIMS1 | c.2134A>C p.S712R | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV53451057; called by muse, mutect2, varscan2
- RIPPLY3 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs531371582, COSV61566468; called by muse, mutect2, varscan2
- RNF145 | c.1310A>C p.E437A (on ENST00000424310 / NM_001199383.2; = p.E465A on NM_144726.2) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50872114; called by muse, mutect2, varscan2
- RYR2 | c.8882A>C p.K2961T | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63711728; called by muse, mutect2, varscan2
- RYR3 | c.2508T>A p.D836E | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.085); catalogued as COSV66807412; called by muse, mutect2
- SARNP | c.22C>T p.L8F | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54479285, COSV54479341; called by muse, mutect2, varscan2
- SCN7A | c.2776A>C p.T926P | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV69274487; called by muse, mutect2, varscan2
- SCN7A | c.2106A>C p.Q702H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV69274490; called by muse, mutect2, varscan2
- SGSM1 | c.782A>G p.N261S | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV68513328; called by muse, mutect2, varscan2
- SH2D4B | c.973G>A p.A325T (on ENST00000646907; = p.A324T on NM_207372.2) | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs527861608, COSV57892410; called by muse, mutect2, varscan2
- SI | c.2095C>T p.L699F | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1299380975, COSV52299699; called by muse, mutect2, varscan2
- SIAH3 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as rs1325336463, COSV68553040; called by muse, mutect2, varscan2
- SKAP1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 264/519 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs761604918, COSV61145889; called by muse, mutect2, varscan2
- SLC30A8 | c.707T>G p.L236R | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV69975905; called by muse, mutect2, varscan2
- SLIT2 | c.131T>G p.L44R | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV56594018; called by muse, mutect2, varscan2
- SLITRK1 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV65675639; called by muse, mutect2, varscan2
- SLITRK1 | c.590T>G p.V197G | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV65677460; called by muse, mutect2, varscan2
- SMC2 | c.865G>C p.D289H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53954780; called by muse, mutect2, varscan2
- SNAI2 | c.745A>C p.T249P | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50080249; called by muse, mutect2, varscan2
- SNRPA | c.688C>T p.Q230* | Nonsense Mutation (SNP) | VAF 14/232 reads (6%) | catalogued as COSV54682524; called by muse, mutect2
- SOST | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1033871363, COSV57012447; called by muse, mutect2, varscan2
- SP4 | c.1765A>T p.T589S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as COSV56026335; called by muse, mutect2, varscan2
- SPANXN1 | c.179A>T p.K60M | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV65123249, COSV65123365; called by muse, mutect2, varscan2
- SPATA31A1 | c.2020A>G p.I674V | Missense Mutation (SNP) | VAF 97/618 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs1444825655; called by muse, mutect2, varscan2
- SPRYD4 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 61/216 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57666012; called by muse, mutect2, varscan2
- SPTLC3 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752474220, COSV65468520; called by muse, mutect2, varscan2
- STARD8 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.317); catalogued as rs149322857, COSV52932202; called by muse, mutect2, varscan2
- SYNE1 | c.16496A>C p.K5499T (on ENST00000367255 / NM_182961.4; = p.K5428T on NM_033071.3) | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV54936582, COSV54962906, COSV99555537; called by muse, mutect2, varscan2
- TAOK3 | c.533T>G p.F178C | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66827663; called by muse, mutect2, varscan2
- TGFB2 | c.726A>C p.K242N | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as COSV65110988; called by muse, mutect2, varscan2
- TIE1 | c.1193C>T p.T398I | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.167); catalogued as COSV65248274, COSV65251282; called by muse, mutect2, varscan2
- TLR4 | c.561T>G p.I187M (on ENST00000355622 / NM_138554.5; = p.I147M on NM_003266.4) | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62924185; called by muse, mutect2, varscan2
- TNFRSF8 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 46/56 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as rs766265540, COSV55800549; called by muse, mutect2, varscan2
- TOGARAM1 | c.665G>C p.G222A | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61889314; called by muse, mutect2, varscan2
- TP53 | c.851del p.T284Kfs*61 | Frame Shift Del (DEL) | VAF 41/71 reads (58%) | catalogued as CD003107, COSV52908002; called by mutect2, pindel, varscan2
- TRAM1L1 | c.1100A>C p.K367T | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60293240; called by muse, mutect2, varscan2
- TRDN | c.1446A>C p.K482N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.063); catalogued as COSV62132361; called by muse, mutect2
- TRPA1 | c.1749T>G p.F583L | Missense Mutation (SNP) | VAF 67/271 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV51573361; called by muse, mutect2, varscan2
- TSPAN12 | c.474G>T p.K158N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56081199; called by muse, mutect2, varscan2
- TTF1 | c.584A>G p.E195G | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV57507192; called by muse, mutect2, varscan2
- TTN | c.102803A>T p.D34268V (on ENST00000591111; = p.D26844V on NM_003319.4) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | PolyPhen benign (0.155); catalogued as COSV60326146; called by muse, mutect2, varscan2
- TTN | c.50492G>T p.C16831F (on ENST00000591111; = p.C9407F on NM_003319.4) | Missense Mutation (SNP) | VAF 38/160 reads (24%) | PolyPhen benign (0.164); catalogued as COSV59889527, COSV60326199; called by muse, mutect2, varscan2
- TTN | c.36749C>A p.A12250D (on ENST00000591111; = p.A4826D on NM_003319.4) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | PolyPhen probably damaging (0.999); catalogued as COSV60326249; called by muse, mutect2, varscan2
- TTN | c.23313A>C p.E7771D (on ENST00000591111; = p.E6844D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | PolyPhen benign (0.009); catalogued as COSV60315445; called by muse, mutect2, varscan2
- TTN | c.16762A>C p.S5588R (on ENST00000591111; = p.S4661R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 115/349 reads (33%) | PolyPhen possibly damaging (0.715); catalogued as COSV60326308; called by muse, mutect2, varscan2
- TTN | c.3938A>G p.K1313R (on ENST00000591111; = p.K1267R on NM_003319.4) | Missense Mutation (SNP) | VAF 35/95 reads (37%) | PolyPhen benign (0.274); catalogued as COSV60326720; called by muse, mutect2, varscan2
- UNC13D | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV52887139; called by muse, mutect2, varscan2
- UPF3A | c.798dup p.E267Rfs*4 | Frame Shift Ins (INS) | VAF 18/34 reads (53%) | catalogued as rs767420916; called by mutect2, varscan2
- USH2A | c.4179A>C p.K1393N | Missense Mutation (SNP) | VAF 30/158 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.131); catalogued as COSV56385498, COSV56391080; called by muse, mutect2, varscan2
- USH2A | c.3790T>A p.S1264T | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.272); catalogued as COSV56430868; called by muse, mutect2, varscan2
- UTRN | c.9935C>T p.S3312L | Missense Mutation (SNP) | VAF 52/201 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs1382115665, COSV62312632; called by muse, mutect2, varscan2
- WDR49 | c.1632T>G p.I544M (on ENST00000308378 / NM_001366158.1; = p.I885M on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as COSV57717340; called by muse, mutect2, varscan2
- WIPF2 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 42/146 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV60275790; called by muse, mutect2, varscan2
- ZBTB41 | c.1331T>A p.F444Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV66360050; called by muse, mutect2, varscan2
- ZDHHC15 | c.202T>G p.F68V | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV64903657; called by muse, mutect2, varscan2
- ZEB1 | c.2378T>A p.I793N | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.77); PolyPhen benign (0.296); catalogued as COSV58054092; called by muse, mutect2, varscan2
- ZEB1 | c.3070G>A p.E1024K | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs975831124, COSV58053159; called by muse, mutect2, varscan2
- ZFP28 | c.2013A>C p.K671N | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56737978; called by muse, mutect2, varscan2
- ZFPM2 | c.1066T>C p.S356P | Missense Mutation (SNP) | VAF 174/444 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV65875717; called by muse, mutect2, varscan2
- ZNF536 | c.3634A>G p.T1212A | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62833471; called by muse, mutect2, varscan2
- ZNF665 | c.397A>T p.R133* (on ENST00000600412; = p.R198* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 73/340 reads (21%) | catalogued as COSV67217438; called by muse, mutect2, varscan2
- ZNF665 | c.308A>C p.E103A (on ENST00000600412; = p.E168A on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/345 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV67217445; called by muse, mutect2, varscan2
- ZNF804B | c.791A>C p.K264T | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV60853182; called by muse, mutect2, varscan2
- ZNF92 | c.589A>G p.R197G (on ENST00000328747 / NM_152626.4; = p.R128G on NM_007139.4) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.06); catalogued as COSV60875952; called by muse, mutect2, varscan2
- ZNF99 | c.443A>G p.N148S | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.752); catalogued as COSV68056654; called by muse, mutect2
- ZSWIM5 | c.2740T>A p.F914I | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55801906; called by muse, mutect2, varscan2
- ZXDC | c.214G>C p.G72R | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.41); catalogued as COSV60448672; called by muse, mutect2, varscan2
- DHX29 | c.1020_1021insG p.F341Vfs*2 | Frame Shift Ins (INS) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- MDN1 | c.6834_6837del p.T2279* | Frame Shift Del (DEL) | VAF 29/194 reads (15%) | called by mutect2, pindel, varscan2
- MICAL1 | c.1430del p.N477Ifs*10 | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | called by mutect2, pindel, varscan2
- PAPOLA | c.869del p.P290Lfs*15 | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | called by pindel, varscan2
- TTK | c.192_211del p.D64Efs*11 | Frame Shift Del (DEL) | VAF 33/71 reads (46%) | called by mutect2, pindel, varscan2
- ZNF26 | c.643_647del p.S215Pfs*2 | Frame Shift Del (DEL) | VAF 30/47 reads (64%) | called by mutect2, pindel, varscan2
- ABCA12 | c.7767A>G p.Q2589= (on ENST00000272895 / NM_173076.3; = p.Q2271= on NM_015657.3) | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV55967584; called by muse, mutect2, varscan2
- ADAMTS17 | c.2706C>G p.P902= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs777524361, COSV51492972; called by muse, mutect2, varscan2
- ANKEF1 | c.1134C>T p.I378= | Silent (SNP) | VAF 42/166 reads (25%) | catalogued as rs773933031, COSV65693601; called by muse, mutect2, varscan2
- APOL2 | c.714G>A p.A238= | Silent (SNP) | VAF 49/166 reads (30%) | catalogued as rs371802979, COSV50773059; called by muse, mutect2, varscan2
- CACNA1E | c.4149T>C p.D1383= | Silent (SNP) | VAF 76/413 reads (18%) | catalogued as rs530293956, COSV62418175; called by muse, mutect2, varscan2
- CAPN12 | c.345T>C p.T115= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as rs1440127912; called by muse, mutect2
- CCL28 | c.30C>G p.A10= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV63150067; called by muse, mutect2, varscan2
- CEACAM7 | c.738C>T p.L246= | Silent (SNP) | VAF 20/164 reads (12%) | catalogued as rs782548650, COSV50074656; called by muse, mutect2, varscan2
- CEMIP2 | c.3180C>T p.L1060= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs372416639; called by muse, mutect2, varscan2
- COBL | c.1308G>A p.Q436= | Silent (SNP) | VAF 48/170 reads (28%) | catalogued as COSV54357429; called by muse, mutect2, varscan2
- COL4A1 | c.3714C>T p.R1238= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs377765047; ClinVar: likely benign; called by muse, mutect2, varscan2
- DDIAS | c.2901T>C p.S967= | Silent (SNP) | VAF 36/82 reads (44%) | catalogued as COSV100231421, COSV61273198; called by muse, mutect2, varscan2
- DGKI | c.2400T>A p.S800= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV55973863; called by muse, mutect2, varscan2
- ERG | c.1287C>T p.H429= (on ENST00000398919 / NM_001243428.1; = p.H405= on NM_004449.4) | Silent (SNP) | VAF 58/106 reads (55%) | catalogued as rs1215562463, COSV55736789; called by muse, mutect2, varscan2
- EVX2 | c.915G>A p.A305= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV57965015; called by muse, mutect2, varscan2
- FBN2 | c.219C>T p.R73= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as rs1208524038, COSV52499031; called by muse, mutect2, varscan2
- FLG2 | c.1158A>C p.G386= | Silent (SNP) | VAF 31/295 reads (11%) | catalogued as COSV66172891; called by muse, mutect2, varscan2
- FOLH1 | c.1984A>C p.R662= | Silent (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.882T>A p.L294= | Silent (SNP) | VAF 19/96 reads (20%) | catalogued as COSV51451510; called by muse, mutect2, varscan2
- HTRA1 | c.1350C>T p.D450= | Silent (SNP) | VAF 23/218 reads (11%) | catalogued as rs374675648; called by muse, mutect2
- ITGAM | c.2409G>C p.V803= (on ENST00000648685 / NM_001145808.2; = p.V802= on NM_000632.4) | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV54942387; called by muse, mutect2, varscan2
- KBTBD2 | c.892T>C p.L298= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV58364288; called by muse, mutect2, varscan2
- KIF5B | c.966C>G p.A322= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV56656128; called by muse, mutect2, varscan2
- LCE1C | c.78C>G p.T26= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as COSV64219206; called by muse, mutect2, varscan2
- LIPT1 | c.541T>C p.L181= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV60740431; called by muse, mutect2
- LRRN1 | c.235T>C p.L79= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as COSV60016084; called by muse, mutect2, varscan2
- MAGEC1 | c.66T>C p.P22= | Silent (SNP) | VAF 51/128 reads (40%) | catalogued as COSV53580740; called by muse, mutect2, varscan2
- MYOM2 | c.3750G>A p.Q1250= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as COSV50767754; called by muse, mutect2, varscan2
- NAV3 | c.540T>C p.S180= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV57110410; called by muse, mutect2, varscan2
- NFIC | c.672C>T p.G224= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs762649968, COSV59410774; called by muse, mutect2, varscan2
- NRXN1 | c.2559A>G p.T853= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as COSV58489598; called by muse, mutect2, varscan2
- NUP98 | c.4122G>A p.L1374= (on ENST00000359171 / NM_001365126.1; = p.L1357= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 128/234 reads (55%) | catalogued as COSV61430017; called by muse, mutect2, varscan2
- OR2M4 | c.201C>T p.S67= | Silent (SNP) | VAF 77/273 reads (28%) | catalogued as COSV60709618; called by muse, mutect2, varscan2
- PCLO | c.15387C>T p.V5129= | Silent (SNP) | VAF 92/277 reads (33%) | catalogued as COSV61663667; called by muse, mutect2, varscan2
- PGR | c.2451G>A p.E817= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV54810208; called by muse, mutect2, varscan2
- PRDM14 | c.1308C>T p.L436= | Silent (SNP) | VAF 32/132 reads (24%) | catalogued as COSV52575237; called by muse, mutect2, varscan2
- PTPRM | c.1989A>G p.A663= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as rs1379390292, COSV59880655; called by muse, mutect2, varscan2
- SLC7A8 | c.447G>A p.P149= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs781585326, COSV57555929; called by muse, mutect2, varscan2
- TNN | c.522G>A p.A174= | Silent (SNP) | VAF 17/20 reads (85%) | catalogued as rs374925420; called by muse, mutect2, varscan2
- TTN | c.12618A>G p.E4206= (on ENST00000591111; = p.E4160= on NM_003319.4) | Silent (SNP) | VAF 53/153 reads (35%) | catalogued as COSV60003557, COSV60326324; called by muse, mutect2, varscan2
- UNC5D | c.1785T>C p.S595= | Silent (SNP) | VAF 45/230 reads (20%) | catalogued as COSV54792158, COSV54833339; called by muse, mutect2, varscan2
- XIRP2 | c.2853T>C p.T951= (on ENST00000628543; = p.T1126= on NM_152381.6) | Silent (SNP) | VAF 19/49 reads (39%) | catalogued as COSV54732179, COSV54739283; called by muse, mutect2, varscan2
- ZFP3 | c.1029G>A p.G343= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as rs146498999, COSV59584069; called by muse, mutect2, varscan2
- ZNF335 | c.2127G>A p.G709= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV100532670, COSV59820036; called by muse, mutect2, varscan2
- ZNF335 | c.852T>A p.R284= | Silent (SNP) | VAF 54/137 reads (39%) | catalogued as COSV59820043; called by muse, mutect2, varscan2
- DCHS2 | n.2455G>A | RNA (SNP) | VAF 25/42 reads (60%) | catalogued as rs770210378, COSV59724821; called by muse, mutect2, varscan2
- HNF4A | c.115+1124A>T | Intron (SNP) | VAF 33/58 reads (57%) | called by muse, mutect2, varscan2
- LINC02145 | n.298T>C | RNA (SNP) | VAF 4/9 reads (44%) | called by mutect2, varscan2
- MIR9-1HG | n.386C>T | RNA (SNP) | VAF 6/29 reads (21%) | catalogued as rs200169407; called by muse, mutect2, varscan2
- NVL | c.2183-6759A>C | Intron (SNP) | VAF 21/80 reads (26%) | catalogued as COSV99895127; called by muse, mutect2, varscan2
- PPP3R1 | chr2:68253049 T>A | 5'Flank (SNP) | VAF 9/31 reads (29%) | catalogued as COSV99310595; called by muse, mutect2, varscan2
- PTGER3 | c.1077+77A>G | Intron (SNP) | VAF 38/116 reads (33%) | called by muse, mutect2, varscan2
- PTGER3 | c.1077+76C>A | Intron (SNP) | VAF 37/113 reads (33%) | catalogued as COSV60695632; called by muse, mutect2, varscan2
- SLC22A17 | n.1433G>A | RNA (SNP) | VAF 16/54 reads (30%) | catalogued as COSV52837329; called by muse, mutect2, varscan2
- TTN | c.34354+555A>C | Intron (SNP) | VAF 30/119 reads (25%) | catalogued as COSV100628938; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23296T>A | Intron (SNP) | VAF 124/314 reads (39%) | catalogued as COSV100530420, COSV59396223, COSV59397972; called by muse, mutect2, varscan2
- XIRP2 | c.*132T>G | 3'UTR (SNP) | VAF 22/62 reads (35%) | catalogued as COSV99739688; called by muse, mutect2, varscan2
